TCGA case TCGA-BS-A0WQ — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: University of Hawaii. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e095a927-d985-4fbd-8093-46c1c6ace4de

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 55.1 years (20,131 days); Year of diagnosis: 2006; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IA; FIGO staging edition year: 1988; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,022 days (5.5 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 0.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 14.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Tamoxifen; Timepoint category: Prior to Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,208 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 2,022 days (5.5 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: Yes; Menopause status: Postmenopausal; Number of pregnancies: 0; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 93 kg; Height: 160 cm; BMI: 36.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BS-A0WQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 140 mg.
  Slide TCGA-BS-A0WQ-01A-02-TSB: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BS-A0WQ-01A-02-BSB: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BS-A0WQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BS-A0WQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: open.
- Follow-up form: History menopausal hormone therapy: Yes, I have taken menopausal hormone therapy in the past, but no longer do; History tamoxifen use: Former User; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 0; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,022 days; disease-specific survival: no event (censored), 2,022 days; disease-free interval: no event (censored), 2,022 days; progression-free interval: no event (censored), 2,022 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BS-A0WQ-01A-21D-A107-01): tumor purity 0.97, ploidy 2.05, whole-genome doublings 0.
